Gene-level copy-number profile of tumor specimen CDDP-ACLV-TTP1-A from CDDP_EAGLE case CDDP-ACLV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76 years.
Specimen CDDP-ACLV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 989df6d0-65a7-48c6-9127-cd72f24c6f15.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACLV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,798 have no estimate.
https://portal.gdc.cancer.gov/files/abea7679-164c-41f3-9f9f-42f30cc852be

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 629; copy number 2: 9,583; copy number 3: 12,788; copy number 4: 15,953; copy number 5: 13,503; copy number 6: 2,314; copy number 7: 557; copy number 8: 984; copy number 9: 895; copy number 10: 315; copy number 11: 421; copy number 12: 248; copy number 13: 275; copy number 14: 27; copy number 15: 80; copy number 16: 40; copy number 17: 8; copy number 19: 83; copy number 20: 6; copy number 22: 4; copy number 25: 33; copy number 27: 25; copy number 29: 17; copy number 31: 1; copy number 32: 3; copy number 33: 2; copy number 46: 1; copy number 48: 2.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:39,141,855–39,172,952, 3 genes (within-gene range 0–2): CSRNP1, AC092053.3, AC092053.2.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:50,569,152–50,611,774, 3 genes (within-gene range 0–3): HEMK1, AC096920.1, CISH.
- chr7:37,032–37,477, 1 gene: AC215522.1.
- chr10:6,709,530–6,740,532, 1 gene: LINP1.
- chr11:65,498,010–65,506,173, 2 genes (within-gene range 0–1): AP000769.2, AP000769.3.
- chr13:31,960,325–31,975,448, 2 genes: AC002525.1, Metazoa_SRP.
- chr13:40,079,106–40,535,807, 4 genes (within-gene range 0–1): LINC00598, LINC00332, RPL17P51, RNY3P9.
- chr13:45,777,242–45,851,753, 1 gene: SIAH3.
- chr13:46,717,423–46,717,688, 1 gene (within-gene range 0–1): AL359880.1.
- chr13:47,825,330–47,835,956, 1 gene: AL138962.1.
- chr13:48,771,128–48,771,827, 1 gene: PSME2P2.
- chr13:51,222,334–51,364,735, 3 genes (within-gene range 0–1): FAM124A, SERPINE3, MIR5693.
- chr16:32,356,981–32,380,049, 2 genes: AC133548.1, ACTR3BP3.
- chr17:4,556,927–4,560,818, 1 gene: GGT6.
- chr17:4,739,833–4,746,119, 1 gene (within-gene range 0–3): ZMYND15.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,486 genes in 89 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,760,669, 15 genes, copy number 9–11: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr1:143,905,487–148,796,325, 161 genes, copy number 9–12 (broad region; genes not listed).
- chr1:149,937,812–155,859,400, 327 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr1:159,927,039–160,647,295, 31 genes, copy number 9–11: IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1.
- chr1:160,796,074–162,370,475, 72 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr1:162,445,549–163,076,802, 13 genes, copy number 9–13: SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4.
- chr2:130,729,070–130,836,994, 5 genes, copy number 9 (within-gene range 8–9): GPR148, AC140481.1, AMER3, CYCSP8, AC133785.1.
- chr5:7,239,781–7,830,081, 10 genes, copy number 9 (within-gene range 6–9): Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2.
- chr5:12,297,399–13,250,662, 8 genes, copy number 9: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5.
- chr5:16,941,843–17,276,843, 8 genes, copy number 10–11: RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P.
- chr5:20,305,565–21,589,372, 10 genes, copy number 9 (within-gene range 8–9): CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2.
- chr5:21,750,673–22,853,344, 7 genes, copy number 9 (within-gene range 7–10): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1.
- chr5:23,262,159–23,528,093, 6 genes, copy number 9–10: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr5:24,487,100–26,399,819, 23 genes, copy number 9: CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P, AC025475.1.
- chr5:28,808,538–31,066,132, 22 genes, copy number 9–10: AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, RPL19P11, AC026421.1.
- chr5:31,400,497–32,110,932, 19 genes, copy number 9–10 (within-gene range 7–11): DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5.
- chr5:32,103,445–33,468,091, 24 genes, copy number 9–11: AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1.
- chr5:34,837,549–35,048,135, 8 genes, copy number 9: AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:36,485,343–37,953,827, 26 genes, copy number 10 (within-gene range 8–10): RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117.
- chr5:39,105,252–40,860,175, 20 genes, copy number 9–12: FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6.
- chr5:41,585,882–43,707,405, 53 genes, copy number 9–10: AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12.
- chr5:45,035,199–51,665,048, 25 genes, copy number 9–10: AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC022433.1, AC091860.2.
- chr7:75,156,639–75,395,434, 13 genes, copy number 15–22 (within-gene range 8–22): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, AC211486.1.
- chr8:60,289,928–67,849,338, 114 genes, copy number 11–19 (within-gene range 11–22) (broad region; genes not listed).
- chr8:69,667,046–74,823,313, 97 genes, copy number 9–17 (within-gene range 7–17) (broad region; genes not listed).
- chr8:80,241,389–81,165,266, 27 genes, copy number 10–14: MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1.
- chr8:97,241,742–113,436,939, 241 genes, copy number 9–27 (within-gene range 7–27) (broad region; genes not listed).
- chr8:115,950,511–120,542,133, 52 genes, copy number 9–22 (within-gene range 8–22): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP.
- chr8:120,913,065–129,683,770, 132 genes, copy number 9–48 (within-gene range 3–48) (broad region; genes not listed).
- chr8:138,130,023–145,066,685, 208 genes, copy number 10–14 (within-gene range 10–20) (broad region; genes not listed).
- chr12:41,188,320–45,216,041, 57 genes, copy number 9–12 (within-gene range 4–12): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1.
- chr12:50,175,788–52,108,261, 64 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr12:52,341,197–57,586,633, 308 genes, copy number 9–13 (broad region; genes not listed).
- chr12:68,248,242–68,957,677, 23 genes, copy number 9–17: IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, AC025423.1, RNU7-4P, AC025423.5, PRELID2P1.
- chr14:34,485,979–34,740,833, 14 genes, copy number 9–10: RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6.
- chr16:32,635,673–33,570,935, 53 genes, copy number 9–13: AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1, IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3, AC142086.5, IGHV1OR16-2, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8, AC145350.2, AC145350.3, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,875,039–33,976,346, 7 genes, copy number 10–13 (within-gene range 8–13): AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5.
- chr16:48,849,919–49,275,579, 5 genes, copy number 9–10: AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2.
- chr18:316,737–2,489,426, 38 genes, copy number 13–19 (within-gene range 4–19): COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr18:13,419,421–15,066,598, 59 genes, copy number 9–13: LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3.

Autosomal genes at a single copy (total copy number 1): 629. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
